Gene-level copy-number profile of specimen HCM-BROD-0444-C43-85O from HCMI case HCM-BROD-0444-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60.4 years (22,064 days).
Specimen HCM-BROD-0444-C43-85O: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f980ed47-4e6c-4379-9476-607d83679aee.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0444-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/140835da-0f10-4fd7-9e27-6e3df4f82ea3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 3,377; copy number 2: 47,027; copy number 3: 1,943; copy number 4: 65; copy number 5: 5,891; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:108,375,838–108,471,002, 4 genes: NBPF5P, SLC25A24P2, AL390038.1, NBPF6.
- chr3:109,707–197,341, 1 gene (within-gene range 0–1): CHL1-AS2.
- chr3:4,896,809–4,985,323, 2 genes: BHLHE40-AS1, BHLHE40.
- chr3:15,254,353–15,341,368, 2 genes (within-gene range 0–1): SH3BP5, RNU6-454P.
- chr3:25,597,905–25,790,039, 7 genes (within-gene range 0–1): TOP2B, AC093416.2, MIR4442, CRIP1P2, NGLY1, AC092798.1, TAF9BP1.
- chr3:39,383,370–39,412,542, 4 genes: SLC25A38, RPSA, SNORA6, SNORA62.
- chr3:195,658,096–195,699,497, 2 genes (within-gene range 0–1): SDHAP2, MIR570.
- chr3:196,142,525–196,432,530, 19 genes: LINC00885, ZDHHC19, Y_RNA, SLC51A, PCYT1A, AC069257.3, AC069257.1, TCTEX1D2, AC069257.2, TM4SF19-TCTEX1D2, TM4SF19-AS1, TM4SF19, RNU6-910P, UBXN7, RNU6-1279P, RN7SL434P, RN7SL738P, AC083822.1, UBXN7-AS1.
- chr3:196,867,856–196,969,060, 6 genes: SENP5, AC016949.1, NCBP2, NCBP2-AS1, NCBP2AS2, PIGZ.
- chr3:197,505,262–197,665,757, 7 genes (within-gene range 0–1): LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.1.
- chr3:197,850,400–198,080,720, 10 genes (within-gene range 0–1): AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P.
- chr9:21,638,285–21,638,676, 1 gene: H3P30.
- chr9:23,632,106–23,632,360, 1 gene: SUMO2P2.
- chr9:23,955,760–23,956,444, 1 gene: AL365204.3.
- chr9:26,796,173–26,892,803, 4 genes: AL451137.1, AL356133.1, CAAP1, H3P31.
- chr9:26,947,039–27,104,728, 4 genes (within-gene range 0–1): IFT74, IFT74-AS1, LRRC19, AL355432.1.
- chr11:112,602,354–112,602,452, 1 gene (within-gene range 0–1): AP003063.1.
- chr11:114,521,645–114,559,895, 2 genes (within-gene range 0–1): NXPE1, AC020549.1.
- chr11:115,920,248–115,950,801, 2 genes: LINC02703, AP000797.2.
- chr11:118,003,634–118,152,888, 4 genes: SMIM35, RN7SL828P, TMPRSS4, SCN4B.
- chr11:124,865,432–124,936,412, 6 genes: ROBO3, AP003501.1, ROBO4, AP003501.2, HEPACAM, HEPN1.
- chr11:128,686,535–128,813,267, 2 genes (within-gene range 0–1): FLI1, SENCR.
- chr11:130,159,782–130,210,362, 1 gene: ST14.
- chr11:134,032,216–134,067,936, 2 genes: LINC02731, AP000911.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,892 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:235,361,153–236,764,631, 37 genes, copy number 5: AL357556.1, AL357556.5, TBCE, RPS21P1, B3GALNT2, MTCYBP14, MTND6P14, MTND5P19, MTND4P10, MTND4LP21, MTND3P8, MTCO3P46, GNG4, FO393422.1, AL583844.1, LYST, LDHAP2, LYST-AS1, MIR1537, RNU6-968P, AL139161.1, LINC02768, NID1, Y_RNA, AL122018.1, GPR137B, ERO1B, RNU2-70P, AL450309.1, EDARADD, ENO1P1, LGALS8, LGALS8-AS1, AL359921.2, AL359921.1, HEATR1, ACTN2.
- chr1:242,671,140–243,500,091, 17 genes, copy number 5 (within-gene range 2–5): AC099785.1, RSL24D1P4, AL445675.1, AL445675.2, AL603825.1, AL606534.3, SEPTIN14P21, CICP21, AL606534.4, LINC01347, RNU6-747P, CEP170, AL606534.1, AL606534.2, SDCCAG8, FCF1P7, MIR4677.
- chr4:49,096–50,124, 1 gene, copy number 7: BNIP3P41.
- chr4:4,117,925–4,157,443, 4 genes, copy number 5: AC116562.1, OR7E103P, UNC93B4, OR7E99P.
- chr4:9,215,405–9,231,233, 4 genes, copy number 5: USP17L11, USP17L12, USP17L13, USP17L14P.
- chr6:105,919–55,579,197, 1,450 genes, copy number 5 (broad region; genes not listed).
- chr7:37,032–159,233,377, 2,933 genes, copy number 5 (broad region; genes not listed).
- chr8:48,551,527–145,066,685, 1,446 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,377. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
